MMRF case MMRF_1617 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/c08bd66a-e697-46cc-96fd-c2af679d94f4

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 47 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 47.6 years (17,400 days); ISS stage: I; Days to last known disease status: 1,162 days (3.2 years); Days to last follow up: 1,162 days (3.2 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 101 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 2 days; Days to treatment end: 101 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 2 days; Days to treatment end: 108 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 146 days; Days to treatment end: 147 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 149 days; Days to treatment end: 149 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 251 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 2 (ECOG 1): M Protein 2.09 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 71.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.2 mg/dL; Immunoglobulin G 35.5 g/L; Immunoglobulin A 1.7 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 2.04 µg/mL; Lactate Dehydrogenase 3.33 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 254 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.65 mmol/L; Albumin 45 g/L; Total Protein 9.3 g/dL; Glucose 12.7 mmol/L; C-Reactive Protein 0.16 mg/dL.
- Day 87 (ECOG 1): M Protein 0.12 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.11 mg/dL; Immunoglobulin G 7.33 g/L; Immunoglobulin A 1.96 g/L; Immunoglobulin M 0.34 g/L; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 9.18 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 250 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.4 mmol/L; Albumin 50 g/L; Total Protein 7.3 g/dL; Glucose 12.4 mmol/L.
- Day 174 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.57 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.2 mg/dL; Immunoglobulin G 7.07 g/L; Immunoglobulin A 1.75 g/L; Immunoglobulin M 0.32 g/L; Hemoglobin 7.32 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 314 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.33 mmol/L; Albumin 46 g/L; Total Protein 6.8 g/dL; Glucose 8.25 mmol/L.
- Day 265 (ECOG 1): M Protein 0.09 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.75 mg/dL; Immunoglobulin G 8.1 g/L; Immunoglobulin A 1.22 g/L; Immunoglobulin M 0.29 g/L; Hemoglobin 8.68 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 248 ×10⁹/L; Albumin 44 g/L; Total Protein 6.7 g/dL.
- Day 373: M Protein 0.08 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.84 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.06 mg/dL; Immunoglobulin G 9.21 g/L; Immunoglobulin A 1.69 g/L; Immunoglobulin M 0.44 g/L; Lactate Dehydrogenase 3.87 µkat/L; Hemoglobin 9.49 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 238 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.5 mmol/L; Albumin 52 g/L; Total Protein 7.8 g/dL; Glucose 8.91 mmol/L.
- Day 441 (ECOG 1): M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.81 mg/dL; Immunoglobulin G 8.1 g/L; Immunoglobulin A 1.64 g/L; Immunoglobulin M 0.43 g/L; Hemoglobin 8.93 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.03 mmol/L; Albumin 41 g/L; Total Protein 6 g/dL; Glucose 10.3 mmol/L.
- Day 555 (ECOG 1): M Protein 0.09 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.82 mg/dL; Immunoglobulin G 8.36 g/L; Immunoglobulin A 1.63 g/L; Immunoglobulin M 0.29 g/L; Hemoglobin 8.8 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.33 mmol/L; Albumin 46 g/L; Total Protein 6.8 g/dL; Glucose 12.2 mmol/L.
- Day 639 (ECOG 1): M Protein 0.09 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.95 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.19 mg/dL; Immunoglobulin G 8.38 g/L; Immunoglobulin A 2 g/L; Immunoglobulin M 0.3 g/L; Hemoglobin 9.18 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.5 mmol/L; Albumin 44 g/L; Total Protein 7.6 g/dL; Glucose 10.6 mmol/L.
- Day 723 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.83 mg/dL; Immunoglobulin G 9.01 g/L; Immunoglobulin A 1.91 g/L; Immunoglobulin M 0.32 g/L; Hemoglobin 9.24 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.43 mmol/L; Albumin 45 g/L; Total Protein 7.1 g/dL; Glucose 10.4 mmol/L.
- Day 835 (ECOG 1): M Protein 0.09 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.75 mg/dL; Immunoglobulin G 10.3 g/L; Immunoglobulin A 2.48 g/L; Immunoglobulin M 0.24 g/L; Hemoglobin 9.3 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.53 mmol/L; Albumin 50 g/L; Total Protein 7.9 g/dL; Glucose 14.2 mmol/L.
- Day 891 (ECOG 0): M Protein 0.08 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.68 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.02 mg/dL; Immunoglobulin G 9.19 g/L; Immunoglobulin A 2.46 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 9.55 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.45 mmol/L; Albumin 48 g/L; Total Protein 7.5 g/dL; Glucose 12.5 mmol/L.
- Day 1,003 (ECOG 0): M Protein 0.07 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.2 mg/dL; Immunoglobulin G 8.99 g/L; Immunoglobulin A 2.22 g/L; Immunoglobulin M 0.22 g/L; Hemoglobin 9.36 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.45 mmol/L; Albumin 48 g/L; Total Protein 7.4 g/dL; Glucose 14.2 mmol/L.
- Day 1,059 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.71 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.68 mg/dL; Immunoglobulin G 8.46 g/L; Immunoglobulin A 2.19 g/L; Immunoglobulin M 0.24 g/L; Hemoglobin 9.55 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 202 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.43 mmol/L; Albumin 48 g/L; Total Protein 7.3 g/dL; Glucose 10.5 mmol/L.
- Day 1,162 (ECOG 0): M Protein 0.11 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.41 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.53 mg/dL; Immunoglobulin G 9.7 g/L; Immunoglobulin A 2.38 g/L; Immunoglobulin M 0.27 g/L; Hemoglobin 9.8 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 239 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.5 mmol/L; Albumin 47 g/L; Total Protein 7.5 g/dL; Glucose 10.3 mmol/L.

Other clinical attributes
- Day 2: Weight: 117 kg; Height: 180 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1617_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 2 days.
- Sample MMRF_1617_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 2 days.
